Gene-level copy-number profile of tumor specimen ALCH-B05D-TTP1-A from ALCHEMIST case ALCH-B05D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.8 years (21,470 days).
Specimen ALCH-B05D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9444b16e-4a63-433c-b5f0-49eff555b0c0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B05D-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/c787a389-2b21-4b74-bf3d-4d6fa1cf47d4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 8,952; copy number 2: 45,480; copy number 3: 4,137; copy number 4: 201; copy number 5: 45; copy number 6: 6; copy number 7: 12; copy number 8: 47; copy number 11: 9.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:76,461,676–76,541,459, 8 genes: DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr8:11,062,647–11,067,089, 1 gene (within-gene range 0–2): AF131215.3.
- chr14:102,545,254–102,555,826, 1 gene: LINC02323.
- chr19:2,212,029–2,215,565, 1 gene (within-gene range 0–1): AC004490.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 119 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:68,332,888–69,738,574, 44 genes, copy number 8: LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1.
- chr12:70,243,002–70,354,993, 2 genes, copy number 5 (within-gene range 4–5): CNOT2, AC092881.1.
- chr14:28,318,141–28,418,612, 1 gene, copy number 6: AL139023.1.
- chr14:31,025,106–31,463,371, 13 genes, copy number 5 (within-gene range 4–5): AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1.
- chr14:32,879,246–33,804,176, 4 genes, copy number 7–8: AL049781.1, NPAS3, AL161851.1, AL161851.2.
- chr14:37,197,913–38,606,098, 16 genes, copy number 7–11: MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1.
- chr14:38,738,155–42,703,655, 34 genes, copy number 5–7 (within-gene range 3–7): LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1, AL442163.2.
- chr14:45,567,995–45,715,952, 2 genes, copy number 6: AL139354.1, LINC02303.
- chr14:47,760,995–47,802,201, 3 genes, copy number 6: MIR548Y, LINC00648, AL121576.1.

Autosomal genes at a single copy (total copy number 1): 6,106. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
